TARGET case TARGET-20-PAUBWU — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/db849a46-f57c-4843-9eeb-53de91287e62

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 147 days.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.7 years (5,719 days); Year of diagnosis: 2011; Days to last follow up: 147 days; Sites of involvement: Central nervous system.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML0631.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 147 days; Days to first event: 147 days; First event: Death; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 15.8 ×10³/µL; Blast Count 1%; Bone Marrow blast count 89.4%.

Biospecimens (1 sample)
- Sample TARGET-20-PAUBWU-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- Overall Survival Time in Days: 147
- WBC at Diagnosis: 15.8
- Bone marrow leukemic blast percentage (%): 89.4
- Peripheral blasts (%): 1
- CNS disease: Yes
- FAB Category: M3
- Cytogenetic Complexity: 1
- Primary Cytogenetic Code: PML-RARA
- ISCN: 46,XX,t(15;17)(q24.1;q21)[20]
- SCT in 1st CR: No
